Somatic mutation profile of tumor specimen MP2PRT-PAUYAK-TMP1-A (aliquot MP2PRT-PAUYAK-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUYAK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (919 days).
Specimen MP2PRT-PAUYAK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce6e2e74-4994-413d-a402-55b3721dfe61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYAK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYAK-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/962afa51-e835-4575-bca1-dd77480aa062

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 152/341 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as rs374323328; called by muse, mutect2, varscan2
- GRIA4 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV56909972; called by muse, mutect2
- TEX2 | c.2233C>T p.R745C (on ENST00000583097 / NM_001288733.2; = p.R752C on NM_018469.5) | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs539307138, COSV51977273; called by muse, mutect2, varscan2
- ELAPOR1 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLCZ1 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 11/250 reads (4%) | called by muse, mutect2
- SETD2 | c.7457T>C p.L2486P | Missense Mutation (SNP) | VAF 251/267 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
